Somatic mutation profile of tumor specimen TCGA-09-2049-01D (aliquot TCGA-09-2049-01D-01W-0799-08) from TCGA case TCGA-09-2049, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 64.1 years (23,410 days).
Specimen TCGA-09-2049-01D: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9d473335-29e3-40a5-9a49-143016752c7b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-09-2049-10A (Blood Derived Normal), aliquot TCGA-09-2049-10A-01W-0799-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fb49995c-75a6-481b-b9d3-ad69d0c59fc0

The open-access MAF lists 157 somatic variants for this specimen: 124 protein-altering or splice-affecting, 31 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 96, Silent 31, Frame Shift Del 10, Nonsense Mutation 6, Splice Site 3, In Frame Del 3, Frame Shift Ins 3, Splice Region 2, Intron 1, Nonstop Mutation 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GPRIN2 | c.298A>C p.T100P | Missense Mutation (SNP) | VAF 9/40 reads (23%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs7090312; called by muse, mutect2, varscan2
- TP53 | c.733G>A p.G245S | Missense Mutation (SNP) | VAF 244/257 reads (95%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs28934575, CM010463, CM900210, CM920674, COSV52661744, COSV52661877, COSV52713951, COSV52839866; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AARS1 | c.781G>C p.D261H | Missense Mutation (SNP) | VAF 31/34 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55749010; called by muse, mutect2, varscan2
- AFTPH | c.2764G>A p.A922T (on ENST00000238855 / NM_203437.3; = p.A895T on NM_017657.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 243/409 reads (59%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as COSV53220816; called by muse, mutect2, varscan2
- ANO10 | c.1156T>G p.S386A | Missense Mutation (SNP) | VAF 62/172 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV52735026; called by muse, mutect2, varscan2
- AQP2 | c.551A>T p.N184I | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52231539; called by muse, mutect2, varscan2
- ASB17 | c.18A>T p.K6N | Missense Mutation (SNP) | VAF 79/325 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.205); catalogued as COSV52411610; called by muse, mutect2, varscan2
- ATRNL1 | c.2170A>T p.S724C | Missense Mutation (SNP) | VAF 88/404 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV61813221; called by muse, mutect2, varscan2
- BCLAF3 | c.664A>G p.K222E | Missense Mutation (SNP) | VAF 130/534 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as COSV61414711; called by muse, mutect2, varscan2
- CD3D | c.434A>T p.N145I | Missense Mutation (SNP) | VAF 10/225 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99416645; called by muse, mutect2
- CD5 | c.917C>A p.A306D | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as COSV61718894; called by muse, mutect2, varscan2
- CERKL | c.833G>C p.G278A (on ENST00000339098 / NM_001030311.2; = p.G252A on NM_201548.5) | Missense Mutation (SNP) | VAF 150/746 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as COSV59212126; called by muse, mutect2, varscan2
- CES4A | c.251A>C p.Y84S | Missense Mutation (SNP) | VAF 21/22 reads (95%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); catalogued as COSV58655069; called by muse, mutect2, varscan2
- CHD5 | c.3499A>G p.M1167V | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.678); catalogued as COSV52422399; called by muse, mutect2, varscan2
- CHRNA3 | c.1268C>T p.S423F | Missense Mutation (SNP) | VAF 87/187 reads (47%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.616); catalogued as rs551101196, COSV58776646; called by muse, mutect2, varscan2
- CHSY3 | c.2553A>T p.L851F | Missense Mutation (SNP) | VAF 152/265 reads (57%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.944); catalogued as COSV59285045; called by muse, mutect2, varscan2
- CLCN1 | c.664G>T p.G222C | Missense Mutation (SNP) | VAF 81/268 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as CM136939, COSV58373335; called by muse, mutect2, varscan2
- COG7 | c.404G>A p.S135N | Missense Mutation (SNP) | VAF 76/778 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100207531; called by muse, mutect2, varscan2
- CUBN | c.7395del p.N2467Tfs*26 | Frame Shift Del (DEL) | VAF 188/470 reads (40%) | catalogued as COSV64724084; called by mutect2, pindel, varscan2
- CYP4F8 | c.446G>A p.R149H | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.258); catalogued as rs774281339; called by muse, mutect2, varscan2
- DCAF1 | c.73C>T p.H25Y | Missense Mutation (SNP) | VAF 162/361 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.063); catalogued as COSV60045786; called by muse, mutect2, varscan2
- DCTN1 | c.2675C>G p.S892* | Nonsense Mutation (SNP) | VAF 208/352 reads (59%) | catalogued as COSV62621211; called by muse, mutect2, varscan2
- DCTN1 | c.2081C>G p.A694G | Missense Mutation (SNP) | VAF 104/343 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.383); catalogued as COSV100720927, COSV99054693; called by muse, mutect2, varscan2
- DEPTOR | c.1102-1G>T p.X368_splice | Splice Site (SNP) | VAF 59/151 reads (39%) | catalogued as COSV53820378; called by muse, mutect2, varscan2
- DST | c.6832C>A p.Q2278K | Missense Mutation (SNP) | VAF 34/167 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.013); catalogued as COSV55033444, COSV99760364; called by muse, mutect2, varscan2
- EEF1G | c.1182C>G p.Y394* | Nonsense Mutation (SNP) | VAF 39/126 reads (31%) | catalogued as COSV100240323; called by muse, mutect2
- EEF1G | c.1180T>C p.Y394H | Missense Mutation (SNP) | VAF 38/124 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs370127965; called by muse, mutect2
- ELN | c.1381G>T p.A461S | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.986); catalogued as COSV52713993; called by muse, mutect2, varscan2
- EPHA7 | c.322G>A p.D108N | Missense Mutation (SNP) | VAF 51/185 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65168886; called by muse, mutect2, varscan2
- EPHX1 | c.733G>C p.G245R | Missense Mutation (SNP) | VAF 140/457 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55303142; called by muse, mutect2
- ERI3 | c.666+1G>C p.X222_splice | Splice Site (SNP) | VAF 29/78 reads (37%) | catalogued as COSV64833110; called by muse, mutect2, varscan2
- ERN2 | c.1352T>C p.M451T | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.028); catalogued as rs1482406292, COSV56836580; called by muse, mutect2, varscan2
- EVX2 | c.789C>A p.Y263* | Nonsense Mutation (SNP) | VAF 29/36 reads (81%) | catalogued as rs993175574, COSV57964694; called by muse, mutect2, varscan2
- FAM161B | c.889A>G p.M297V (on ENST00000651776; = p.M234V on NM_152445.3) | Missense Mutation (SNP) | VAF 22/125 reads (18%) | SIFT tolerated (0.71); PolyPhen benign (0.007); catalogued as rs560808582, COSV54103718; called by muse, mutect2, varscan2
- FAM53B | c.794G>A p.R265H | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV99784889; called by muse, mutect2
- FAP | c.2222C>A p.T741K | Missense Mutation (SNP) | VAF 102/1184 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV51866042; called by muse, mutect2
- FAT3 | c.8333C>G p.A2778G | Missense Mutation (SNP) | VAF 33/121 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.006); catalogued as rs1355011675, COSV53158104; called by muse, mutect2, varscan2
- FGF12 | c.145T>C p.F49L | Missense Mutation (SNP) | VAF 39/245 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.02); catalogued as COSV53183014; called by muse, mutect2, varscan2
- FRY | c.5965G>T p.G1989C | Missense Mutation (SNP) | VAF 91/121 reads (75%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.956); catalogued as COSV66576640; called by muse, mutect2, varscan2
- GFRAL | c.371G>T p.G124V | Missense Mutation (SNP) | VAF 334/2247 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as COSV61230253; called by muse, mutect2, varscan2
- GFRAL | c.372A>T p.G124= | Splice Region (SNP) | VAF 340/2273 reads (15%) | catalogued as rs200048676, COSV100475043; called by muse, mutect2, varscan2
- GLRA1 | c.607G>T p.A203S | Missense Mutation (SNP) | VAF 92/166 reads (55%) | SIFT deleterious (0.03); PolyPhen benign (0.07); catalogued as COSV51012987; called by muse, mutect2, varscan2
- GOLGB1 | c.3221A>C p.Q1074P | Missense Mutation (SNP) | VAF 43/299 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.083); catalogued as COSV61469508; called by muse, mutect2, varscan2
- GPR15 | c.1013C>A p.T338N | Missense Mutation (SNP) | VAF 49/197 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.073); catalogued as COSV52521214; called by muse, mutect2, varscan2
- HCFC1 | c.109C>T p.R37C | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV60074789, COSV60076091; called by muse, varscan2
- HDDC3 | c.364G>C p.D122H | Missense Mutation (SNP) | VAF 29/52 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57746625; called by muse, mutect2, varscan2
- HEATR5B | c.5011G>A p.A1671T | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV51857263; called by muse, mutect2, varscan2
- HMBOX1 | c.802C>G p.R268G | Missense Mutation (SNP) | VAF 62/175 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV55066913, COSV55071131; called by muse, mutect2, varscan2
- HMCN1 | c.1516G>T p.G506C | Missense Mutation (SNP) | VAF 161/748 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54929516; called by muse, mutect2, varscan2
- HNMT | c.601T>A p.S201T | Missense Mutation (SNP) | VAF 84/272 reads (31%) | SIFT tolerated (0.32); PolyPhen benign (0.125); catalogued as COSV54509803; called by muse, mutect2, varscan2
- HNRNPH3 | c.1040G>C p.*347Sext*32 | Nonstop Mutation (SNP) | VAF 27/103 reads (26%) | catalogued as COSV56260433; called by muse, mutect2, varscan2
- IGSF10 | c.1292A>G p.Q431R | Missense Mutation (SNP) | VAF 176/354 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56790229; called by muse, varscan2
- INSRR | c.2092G>A p.V698I | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV63876336; called by muse, mutect2, varscan2
- INTS7 | c.1258G>A p.A420T | Missense Mutation (SNP) | VAF 65/325 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.034); catalogued as COSV100877480; called by muse, mutect2, varscan2
- ITGA4 | c.1089A>T p.K363N | Missense Mutation (SNP) | VAF 711/867 reads (82%) | SIFT deleterious (0.03); PolyPhen benign (0.115); catalogued as COSV52002987; called by muse, mutect2, varscan2
- KAT6A | c.1753G>A p.V585M | Missense Mutation (SNP) | VAF 42/185 reads (23%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.878); catalogued as COSV55910765; called by muse, varscan2
- KDM5A | c.3685C>T p.L1229F | Missense Mutation (SNP) | VAF 70/74 reads (95%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66995424; called by muse, mutect2, varscan2
- KLF17 | c.726G>T p.Q242H | Missense Mutation (SNP) | VAF 35/132 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.058); catalogued as COSV64856876; called by muse, mutect2, varscan2
- KLF8 | c.181G>A p.A61T | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV63848547; called by muse, mutect2, varscan2
- LAMTOR5 | c.259C>A p.H87N (on ENST00000602318 / NM_001382293.1; = p.H169N on NM_006402.3) | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.776); catalogued as COSV56679425; called by muse, mutect2, varscan2
- LRRK1 | c.4203G>C p.E1401D | Missense Mutation (SNP) | VAF 21/181 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0.028); catalogued as COSV52623251; called by muse, mutect2, varscan2
- MAGEC1 | c.2569T>A p.S857T | Missense Mutation (SNP) | VAF 224/611 reads (37%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); catalogued as COSV53579065; called by muse, mutect2, varscan2
- MAP7D1 | c.2387A>G p.E796G | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs748149585, COSV60217533; called by muse, mutect2, varscan2
- MC5R | c.512C>T p.T171M | Missense Mutation (SNP) | VAF 98/291 reads (34%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.775); catalogued as rs762169294, COSV61254230; called by muse, mutect2, varscan2
- MMAA | c.824T>C p.I275T | Missense Mutation (SNP) | VAF 66/712 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs1204400776, COSV55581428; called by muse, mutect2
- MYO18B | c.6667C>A p.P2223T | Missense Mutation (SNP) | VAF 27/50 reads (54%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs753096037, COSV59144757; called by muse, mutect2, varscan2
- NAGK | c.478G>A p.A160T | Missense Mutation (SNP) | VAF 157/525 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.425); catalogued as rs183509027, COSV99730580; called by muse, mutect2, varscan2
- NDRG3 | c.1043C>A p.T348N (on ENST00000349004 / NM_032013.4; = p.T336N on NM_022477.4) | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.143); catalogued as COSV62423063; called by muse, mutect2, varscan2
- OR10J1 | c.525C>A p.H175Q | Missense Mutation (SNP) | VAF 46/885 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV101419846; called by muse, mutect2
- OR10X1 | c.154C>A p.L52I | Missense Mutation (SNP) | VAF 69/540 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as COSV100936640; called by muse, mutect2, varscan2
- OR10X1 | c.153C>A p.Y51* | Nonsense Mutation (SNP) | VAF 64/522 reads (12%) | catalogued as COSV100936641; called by muse, varscan2
- OR12D3 | c.338T>A p.L113Q | Missense Mutation (SNP) | VAF 173/463 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV65829668; called by muse, mutect2, varscan2
- OR2M3 | c.398C>A p.T133N | Missense Mutation (SNP) | VAF 300/1590 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.104); catalogued as COSV71758888, COSV71759379; called by muse, mutect2, varscan2
- PCDH9 | c.3041A>G p.N1014S | Missense Mutation (SNP) | VAF 105/141 reads (74%) | SIFT tolerated (0.75); PolyPhen benign (0.026); catalogued as COSV60579574; called by muse, mutect2, varscan2
- PCOLCE2 | c.867T>C p.G289= | Splice Region (SNP) | VAF 111/514 reads (22%) | catalogued as COSV56001246; called by muse, mutect2, varscan2
- PENK | c.513C>A p.H171Q | Missense Mutation (SNP) | VAF 60/407 reads (15%) | SIFT tolerated (0.61); PolyPhen benign (0.034); catalogued as COSV100152290; called by muse, mutect2, varscan2
- PHC2 | c.2250G>C p.L750F (on ENST00000257118 / NM_198040.2; = p.L215F on NM_004427.4) | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.737); catalogued as COSV57107199; called by muse, mutect2, varscan2
- PKLR | c.866G>T p.R289L | Missense Mutation (SNP) | VAF 19/120 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.588); catalogued as COSV61362227, COSV61362483, COSV61362486; called by muse, mutect2, varscan2
- PKP4 | c.2368A>T p.K790* | Nonsense Mutation (SNP) | VAF 46/171 reads (27%) | catalogued as COSV61579981; called by muse, mutect2, varscan2
- PLEKHF2 | c.718G>A p.D240N | Missense Mutation (SNP) | VAF 68/242 reads (28%) | SIFT tolerated (0.74); PolyPhen possibly damaging (0.811); catalogued as COSV59542187; called by muse, mutect2, varscan2
- PLXNA2 | c.1894G>C p.G632R | Missense Mutation (SNP) | VAF 114/766 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0.366); catalogued as COSV65443833; called by muse, mutect2, varscan2
- POLRMT | c.420G>T p.L140F | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.467); catalogued as COSV101648666; called by muse, mutect2
- RESF1 | c.1757C>G p.A586G | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV57024716; called by muse, mutect2, varscan2
- RESF1 | c.2965_2968del p.N989Efs*4 | Frame Shift Del (DEL) | VAF 8/66 reads (12%) | catalogued as rs745625486; called by pindel, varscan2
- RICTOR | c.4118C>T p.S1373F | Missense Mutation (SNP) | VAF 143/431 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs746736711, COSV57128228; called by muse, mutect2, varscan2
- RNASE7 | c.379A>C p.N127H | Missense Mutation (SNP) | VAF 107/383 reads (28%) | SIFT tolerated (0.5); PolyPhen benign (0.011); catalogued as COSV53877297; called by muse, mutect2, varscan2
- ROR1 | c.2590A>G p.S864G | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.931); catalogued as COSV64291697; called by muse, mutect2, varscan2
- RXRA | c.1190A>G p.Y397C | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs901061760, COSV62684376; called by muse, mutect2, varscan2
- SLC20A2 | c.1554G>T p.W518C | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.096); catalogued as COSV60606125; called by muse, varscan2
- SLC4A5 | c.1406G>T p.G469V | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.801); catalogued as COSV61031425; called by muse, mutect2, varscan2
- TACR1 | c.1132T>G p.S378A | Missense Mutation (SNP) | VAF 70/255 reads (27%) | SIFT tolerated (0.83); PolyPhen benign (0.001); catalogued as COSV59482051; called by muse, mutect2, varscan2
- TDRD10 | c.570T>G p.H190Q | Missense Mutation (SNP) | VAF 104/659 reads (16%) | SIFT tolerated (0.37); PolyPhen benign (0.1); catalogued as COSV52726621; called by muse, mutect2, varscan2
- TESMIN | c.1328A>T p.H443L | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV54834527; called by muse, mutect2, varscan2
- TJP1 | c.5170C>G p.Q1724E | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as COSV62045108; called by muse, mutect2, varscan2
- TMEM45A | c.664A>T p.T222S | Missense Mutation (SNP) | VAF 253/1249 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.136); catalogued as COSV60255180; called by muse, mutect2, varscan2
- TMPRSS15 | c.1369A>T p.N457Y | Missense Mutation (SNP) | VAF 32/103 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53046331; called by muse, mutect2, varscan2
- TPD52 | c.428T>G p.L143* (on ENST00000379097 / NM_001025252.3; = p.L103* on NM_005079.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 96/370 reads (26%) | catalogued as COSV100990772; called by muse, mutect2, varscan2
- TRAF3IP1 | c.1677A>T p.K559N | Missense Mutation (SNP) | VAF 38/444 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.872); catalogued as COSV64853908; called by muse, mutect2
- TRIM36 | c.1285G>A p.V429I | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (0.29); PolyPhen benign (0.012); catalogued as COSV56688056, COSV56692531; called by muse, mutect2, varscan2
- USP7 | c.569C>T p.T190I | Missense Mutation (SNP) | VAF 76/258 reads (29%) | SIFT tolerated (0.63); PolyPhen benign (0.263); catalogued as COSV61216796; called by muse, mutect2, varscan2
- VDAC2 | c.122A>G p.D41G | Missense Mutation (SNP) | VAF 44/150 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.432); catalogued as rs749837778, COSV53687210; called by muse, mutect2, varscan2
- VPS52 | c.611C>G p.A204G | Missense Mutation (SNP) | VAF 49/208 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.113); catalogued as COSV71403597; called by muse, mutect2, varscan2
- VWA5A | c.652C>G p.L218V | Missense Mutation (SNP) | VAF 59/147 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV100795638; called by muse, mutect2, varscan2
- WFIKKN2 | c.1435G>T p.G479C | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100259832; called by muse, mutect2, varscan2
- WHRN | c.479C>G p.S160W | Missense Mutation (SNP) | VAF 21/33 reads (64%) | SIFT deleterious (0.02); PolyPhen benign (0.161); catalogued as COSV54333867; called by muse, mutect2, varscan2
- ZDHHC19 | c.878C>T p.A293V | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs780219119, COSV56349666; called by muse, mutect2, varscan2
- ZNF280A | c.303G>A p.M101I | Missense Mutation (SNP) | VAF 74/160 reads (46%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs939186362, COSV57481906; called by muse, mutect2, varscan2
- ZNF385B | c.428C>G p.P143R | Missense Mutation (SNP) | VAF 115/996 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV61180431; called by muse, mutect2, varscan2
- ZNF680 | c.56C>A p.A19D | Missense Mutation (SNP) | VAF 59/277 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.657); catalogued as COSV59017486, COSV59017806; called by muse, mutect2, varscan2
- ACCSL | c.571_572insT p.E191Vfs*3 | Frame Shift Ins (INS) | VAF 160/604 reads (26%) | called by mutect2, pindel*, varscan2
- ASPH | c.833-13_833-2del p.X278_splice | Splice Site (DEL) | VAF 18/85 reads (21%) | called by mutect2, pindel, varscan2
- C10orf90 | c.574_601del p.S192Tfs*7 | Frame Shift Del (DEL) | VAF 48/204 reads (24%) | called by mutect2, pindel
- CETN2 | c.444_449del p.E148_A149del | In Frame Del (DEL) | VAF 40/142 reads (28%) | called by mutect2, pindel, varscan2
- CRYBG1 | c.2212_2213insAGAAAGTAAT p.P738Qfs*11 | Frame Shift Ins (INS) | VAF 12/32 reads (38%) | called by mutect2, pindel*, varscan2
- FUBP1 | c.1422_1448del p.P475_P483del | In Frame Del (DEL) | VAF 20/70 reads (29%) | called by mutect2, pindel
- KLHDC8B | c.1012del p.A338Pfs*52 | Frame Shift Del (DEL) | VAF 10/14 reads (71%) | called by mutect2, pindel*, varscan2
- MEX3A | c.730del p.A244Qfs*234 | Frame Shift Del (DEL) | VAF 22/57 reads (39%) | called by mutect2, pindel, varscan2
- MYO7B | c.2759del p.G920Afs*6 | Frame Shift Del (DEL) | VAF 5/17 reads (29%) | called by mutect2, pindel, varscan2
- PIK3CG | c.66_80del p.R22_R26del | In Frame Del (DEL) | VAF 19/82 reads (23%) | called by pindel, varscan2
- POLDIP2 | c.655del p.A219Pfs*34 | Frame Shift Del (DEL) | VAF 6/24 reads (25%) | called by mutect2, pindel
- RICTOR | c.4530_4537del p.L1512Tfs*4 | Frame Shift Del (DEL) | VAF 42/161 reads (26%) | called by mutect2, pindel, varscan2
- SARS1 | c.93dup p.L32Tfs*16 | Frame Shift Ins (INS) | VAF 6/30 reads (20%) | called by mutect2, pindel, varscan2
- ZDHHC15 | c.630del p.K210Nfs*19 | Frame Shift Del (DEL) | VAF 16/115 reads (14%) | called by mutect2, pindel, varscan2
- ZNF264 | c.1806_1822del p.L604Ffs*5 | Frame Shift Del (DEL) | VAF 35/118 reads (30%) | called by mutect2, pindel, varscan2
- ACSBG2 | c.1014C>T p.S338= | Silent (SNP) | VAF 54/117 reads (46%) | catalogued as COSV53127040; called by muse, mutect2, varscan2
- ANKRD24 | c.315C>A p.G105= | Silent (SNP) | VAF 11/16 reads (69%) | catalogued as rs746444011, COSV53674556; called by muse, mutect2, varscan2
- C2orf16 | c.3618A>G p.Q1206= | Silent (SNP) | VAF 32/128 reads (25%) | catalogued as COSV62677583; called by muse, mutect2, varscan2
- COL6A6 | c.3705T>A p.T1235= | Silent (SNP) | VAF 71/259 reads (27%) | catalogued as COSV62033866; called by muse, mutect2, varscan2
- CREBBP | c.4401G>C p.V1467= | Silent (SNP) | VAF 37/101 reads (37%) | catalogued as CD148335, COSV52136106; called by muse, mutect2, varscan2
- CTSG | c.420G>A p.T140= | Silent (SNP) | VAF 156/585 reads (27%) | catalogued as rs1452143795, COSV53535120; called by muse, mutect2, varscan2
- DEFB129 | c.387C>A p.T129= | Silent (SNP) | VAF 101/518 reads (19%) | catalogued as rs1322221665, COSV55731899; called by muse, mutect2, varscan2
- DNAJC22 | c.534C>T p.L178= | Silent (SNP) | VAF 22/106 reads (21%) | catalogued as COSV67711592; called by muse, mutect2, varscan2
- GABBR1 | c.1092A>T p.G364= | Silent (SNP) | VAF 13/67 reads (19%) | catalogued as COSV63544053; called by muse, mutect2, varscan2
- GNRHR | c.126T>C p.T42= | Silent (SNP) | VAF 26/196 reads (13%) | catalogued as COSV56934533; called by muse, mutect2, varscan2
- GSAP | c.963C>G p.T321= | Silent (SNP) | VAF 129/688 reads (19%) | catalogued as rs758712261, COSV99990139; called by muse, mutect2, varscan2
- HK1 | c.1461G>T p.V487= | Silent (SNP) | VAF 14/42 reads (33%) | catalogued as rs750415580, COSV100066390; called by muse, mutect2, varscan2
- IFT140 | c.2916C>T p.D972= | Silent (SNP) | VAF 5/10 reads (50%) | catalogued as rs148945612; called by muse, mutect2, varscan2
- INTS5 | c.720C>T p.S240= | Silent (SNP) | VAF 7/40 reads (18%) | catalogued as COSV57953112; called by muse, mutect2, varscan2
- KCMF1 | c.942A>C p.A314= | Silent (SNP) | VAF 23/133 reads (17%) | catalogued as COSV69053254, COSV69054533; called by muse, mutect2, varscan2
- KIFC2 | c.1254A>C p.P418= | Silent (SNP) | VAF 10/25 reads (40%) | catalogued as COSV56762495; called by muse, mutect2, varscan2
- LCK | c.1302C>T p.V434= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as rs188058742, COSV60742156; called by muse, mutect2, varscan2
- MDH1B | c.1119A>G p.G373= | Silent (SNP) | VAF 84/463 reads (18%) | catalogued as COSV65591021; called by muse, mutect2, varscan2
- MDM4 | c.855G>A p.E285= | Silent (SNP) | VAF 45/300 reads (15%) | catalogued as rs1262032123, COSV65796518; called by muse, mutect2, varscan2
- MEF2A | c.951C>A p.T317= (on ENST00000557942 / NM_001319206.2; = p.T311= on NM_005587.4 and 8 other RefSeq transcripts) | Silent (SNP) | VAF 19/213 reads (9%) | catalogued as COSV100573706; called by muse, mutect2
- MFSD4A | c.684C>A p.L228= | Silent (SNP) | VAF 6/70 reads (9%) | catalogued as COSV100901507; called by muse, mutect2
- NCR3 | c.295C>A p.R99= | Silent (SNP) | VAF 107/517 reads (21%) | catalogued as COSV53000507, COSV99278988; called by muse, mutect2, varscan2
- OR1S2 | c.567C>T p.H189= | Silent (SNP) | VAF 100/334 reads (30%) | catalogued as rs149451220, COSV100224151; called by muse, mutect2, varscan2
- OTULIN | c.363G>T p.R121= | Silent (SNP) | VAF 64/319 reads (20%) | catalogued as COSV52506682; called by muse, mutect2, varscan2
- PARM1 | c.582G>A p.E194= | Silent (SNP) | VAF 469/1050 reads (45%) | catalogued as COSV100268016; called by muse, mutect2, varscan2
- PSENEN | c.267G>C p.G89= | Silent (SNP) | VAF 11/22 reads (50%) | catalogued as COSV53076115; called by muse, mutect2, varscan2
- PXDN | c.750C>G p.S250= | Silent (SNP) | VAF 9/42 reads (21%) | catalogued as COSV53233278, COSV53243625; called by muse, mutect2, varscan2
- TEKT4 | c.636C>A p.I212= | Silent (SNP) | VAF 17/43 reads (40%) | catalogued as rs186821220, COSV54627468; called by muse, mutect2, varscan2
- VNN1 | c.1431G>A p.G477= | Silent (SNP) | VAF 205/215 reads (95%) | catalogued as COSV63390716; called by muse, mutect2, varscan2
- WFIKKN2 | c.1434G>T p.S478= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as COSV100259826; called by muse, mutect2, varscan2
- ZFYVE26 | c.2034T>C p.F678= | Silent (SNP) | VAF 15/130 reads (12%) | catalogued as COSV61332317; called by muse, mutect2, varscan2
- PDLIM3 | c.162-1665G>C | Intron (SNP) | VAF 97/231 reads (42%) | catalogued as COSV52980840; called by muse, mutect2, varscan2
- SNORD115-19 | n.75T>A | RNA (SNP) | VAF 14/61 reads (23%) | called by muse, mutect2, varscan2
